MMRF case MMRF_1719 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d8e3478c-0c99-4fda-b913-09a962a3dcbf

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.0 years (24,097 days); ISS stage: III; Days to last known disease status: 1,066 days (2.9 years); Days to last follow up: 1,066 days (2.9 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 197 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 10 days; Days to treatment end: 51 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 10 days; Days to treatment end: 197 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 199 days; Days to treatment end: 203 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 218 days; Days to treatment end: 310 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 310 days; Days to treatment end: 419 days (1.1 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1: M Protein 2.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 21 mg/dL; Immunoglobulin G 35.9 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.53 g/L; Beta 2 Microglobulin 13.7 µg/mL; Lactate Dehydrogenase 7.47 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 263 ×10⁹/L; Creatinine 226 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.78 mmol/L; Albumin 50 g/L; Total Protein 9.7 g/dL; Glucose 3.63 mmol/L.
- Day 79 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.98 mg/dL; Immunoglobulin G 4.43 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.64 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 175 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.05 mmol/L; Albumin 38 g/L; Total Protein 5.9 g/dL; Glucose 5.28 mmol/L.
- Day 190 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.47 mg/dL; Immunoglobulin G 3.86 g/L; Immunoglobulin A 0.73 g/L; Immunoglobulin M 0.67 g/L; Beta 2 Microglobulin 4.52 µg/mL; Lactate Dehydrogenase 6.92 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 156 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 5.8 g/dL; Glucose 5.39 mmol/L.
- Day 282 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.83 mg/dL; Immunoglobulin G 4.5 g/L; Immunoglobulin A 0.88 g/L; Immunoglobulin M 0.92 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 164 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 8.03 mmol/L.
- Day 344 (ECOG 1): Hemoglobin 7.38 mmol/L; Leukocytes 2.1 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 122 ×10⁹/L.
- Day 443 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.11 mg/dL; Immunoglobulin G 9.01 g/L; Immunoglobulin A 1.57 g/L; Immunoglobulin M 0.63 g/L; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 85 ×10⁹/L; Creatinine 351 µmol/L; Blood Urea Nitrogen 13.2 mmol/L; Calcium 1.93 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 7.65 mmol/L.
- Day 541 (ECOG 1): Hemoglobin 6.88 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 93 ×10⁹/L.
- Day 632 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.08 mg/dL; Immunoglobulin G 6.26 g/L; Immunoglobulin A 1.48 g/L; Immunoglobulin M 1.41 g/L; Beta 2 Microglobulin 33.6 µg/mL; Hemoglobin 5.95 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 6.3 ×10⁹/L; Platelets 141 ×10⁹/L.
- Day 723 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.89 mg/dL; Immunoglobulin G 5.38 g/L; Immunoglobulin A 1.24 g/L; Immunoglobulin M 1.8 g/L; Beta 2 Microglobulin 36.6 µg/mL; Hemoglobin 8.37 mmol/L; Leukocytes 9.9 ×10⁹/L; Absolute Neutrophil 8.4 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 892 µmol/L; Blood Urea Nitrogen 15 mmol/L; Calcium 2.1 mmol/L; Albumin 32 g/L; Total Protein 5.5 g/dL; Glucose 4.95 mmol/L.
- Day 814: Hemoglobin 8.06 mmol/L; Leukocytes 10.5 ×10⁹/L; Absolute Neutrophil 8.2 ×10⁹/L; Platelets 170 ×10⁹/L.
- Day 891: Lactate Dehydrogenase 8.74 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 12.2 ×10⁹/L; Absolute Neutrophil 10.6 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 996 µmol/L; Blood Urea Nitrogen 19.3 mmol/L; Calcium 2.15 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 6.11 mmol/L.
- Day 975 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 9.2 mg/dL; Immunoglobulin G 1.17 g/L; Immunoglobulin A 5.24 g/L; Immunoglobulin M 3.29 g/L; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 13.9 ×10⁹/L; Absolute Neutrophil 11.9 ×10⁹/L; Platelets 252 ×10⁹/L; Creatinine 898 µmol/L; Blood Urea Nitrogen 15.7 mmol/L; Calcium 2.35 mmol/L; Albumin 35 g/L; Total Protein 6.3 g/dL; Glucose 7.98 mmol/L.
- Day 1,066 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.24 mg/dL; Immunoglobulin G 4.94 g/L; Immunoglobulin A 0.91 g/L; Immunoglobulin M 2.39 g/L; Hemoglobin 7.01 mmol/L; Leukocytes 11.5 ×10⁹/L; Absolute Neutrophil 9.1 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 1090 µmol/L; Blood Urea Nitrogen 16.1 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 5.8 g/dL; Glucose 5.94 mmol/L.

Other clinical attributes
- Day 1: Weight: 77 kg; Height: 193 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Prostate Cancer.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1719_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1719_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
